Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3885, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3885-01A (Primary Tumor).

Diagnosis

In (I) there is a moderately to poorly differentiated, invasive, adenocarcinoma of the colon (rectal carcinoma) with penetration of all wall layers and vascular infiltration. There are lymph node metastases [p T 3, L1, V1, pN1 (here 3/19)] and the resection margins are free. In (II) there are free anastomosis rings.

Tumor classification summary:

ICDO-DA M 8140/3

G 2 to 3, p T 3, L1, V1, p N 1 (3/19), consistent with R 0.

Source: NCI Genomic Data Commons file 8ac637d6-e4cb-41e8-8874-daeb3d1e26d2 (TCGA-AG-3885.9B85566F-B749-4075-8588-8A3F2F85990A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).